Somatic mutation profile of tumor specimen TCGA-MT-A67G-01A (aliquot TCGA-MT-A67G-01A-11D-A30E-08) from TCGA case TCGA-MT-A67G, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.1 years (19,394 days).
Specimen TCGA-MT-A67G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f09350af-b50c-45c1-83ef-3d57976d797e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MT-A67G-10A (Blood Derived Normal), aliquot TCGA-MT-A67G-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edc37e52-d554-489e-a1af-8f34a4fa4f09

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, 3'Flank 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF26B | c.6070C>T p.R2024C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs367632094, COSV63636986; called by muse, mutect2
- AC090517.4 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777989146, COSV50996138; called by muse, mutect2, varscan2
- AQP6 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs776563266, COSV100210096; called by mutect2, varscan2
- CAPZA3 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs966853531, COSV56853557, COSV56853654; called by muse, mutect2
- CHRNA4 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs772253190, COSV100937359; called by muse, mutect2, varscan2
- DBF4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.447); catalogued as COSV99719174; called by muse, mutect2, varscan2
- DDX11 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as rs1427634316, COSV52507258; called by muse, mutect2, varscan2
- EDNRA | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs765457542, COSV100163238; called by muse, mutect2, varscan2
- ERBB2 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs150203173; called by muse, mutect2, varscan2
- FCRLA | c.362G>A p.R121H (on ENST00000367959; = p.R98H on NM_032738.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs1382394086, COSV99375701; called by muse, mutect2
- HCN2 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99241342; called by muse, mutect2, varscan2
- HHAT | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV54807620, COSV99802836, COSV99805987; called by muse, mutect2, varscan2
- HTR7 | c.695T>C p.L232S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV53282402; called by muse, mutect2, varscan2
- IGF2BP1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as COSV99288327; called by muse, mutect2, varscan2
- KDM6A | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773995635, COSV65037772; called by muse, mutect2, varscan2
- LDB3 | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99554812; called by muse, mutect2, varscan2
- LLGL1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs757927589, COSV57497023; called by muse, mutect2, varscan2
- MIS18BP1 | c.657C>T p.Y219= | Splice Region (SNP) | VAF 10/104 reads (10%) | catalogued as rs770194411, COSV60370498; called by muse, mutect2
- MTMR1 | c.627C>G p.N209K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV100953840; called by muse, mutect2, varscan2
- MXD4 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs376861289, COSV100455850; called by muse, mutect2, varscan2
- MYL9 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs571910074, COSV99640948; called by muse, mutect2
- NSUN7 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100348899; called by muse, mutect2
- PDK1 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as COSV99961139; called by muse, mutect2, varscan2
- PKD2 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV99416930; called by muse, mutect2, varscan2
- PKN1 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs754404338, COSV52875136; called by muse, mutect2, varscan2
- POLG | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as rs1248995315, COSV99174532; called by muse, mutect2
- RBM15B | c.425T>A p.L142H | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as COSV100081935; called by muse, mutect2, varscan2
- RGS3 | c.590G>A p.R197K (on ENST00000350696 / NM_001282923.2; = p.R85K on NM_017790.4) | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV100464653; called by muse, mutect2
- SCYL1 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as rs752403987, COSV54215664; called by muse, mutect2, varscan2
- SLC10A2 | c.555A>C p.K185N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99807674; called by muse, mutect2
- SLC4A4 | c.2360C>T p.P787L (on ENST00000264485 / NM_001098484.3; = p.P743L on NM_003759.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761601854, COSV52616704; called by muse, mutect2, varscan2
- TRPV2 | c.2099A>G p.E700G | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as rs1300512594, COSV100641130; called by muse, mutect2, varscan2
- TXNRD1 | c.326G>A p.G109E (on ENST00000525566 / NM_001093771.3; = p.G11E on NM_003330.4) | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168492778, COSV100723323; called by muse, mutect2, varscan2
- USO1 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV99362583; called by muse, mutect2, varscan2
- WDR33 | c.3239G>A p.R1080H | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs775688867, COSV100459640; called by muse, mutect2, varscan2
- WDR72 | c.3205G>A p.V1069M | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs549997856, COSV100854272; called by muse, varscan2
- ZNF629 | c.1132G>C p.V378L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs369298747; called by muse, mutect2, varscan2
- ZNF682 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs192180348, COSV62068918; called by muse, mutect2, varscan2
- ARVCF | c.2427C>T p.L809= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs371327010; called by muse, mutect2
- DNAH1 | c.1932C>T p.D644= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs375044038, COSV70226587; called by mutect2, varscan2
- FBXO3 | c.819C>T p.H273= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs1227895110, COSV99682087; called by muse, mutect2
- GAPT | c.183C>T p.F61= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100576246, COSV59246775; called by muse, mutect2, varscan2
- KIFAP3 | c.2370T>C p.Y790= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100846761; called by muse, varscan2
- MYLK | c.903G>A p.Q301= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV60608676; called by muse, mutect2, varscan2
- NINL | c.2328G>A p.S776= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs144928426, COSV99624722; called by muse, mutect2, varscan2
- PCDHB8 | c.2160G>T p.A720= | Silent (SNP) | VAF 32/203 reads (16%) | catalogued as COSV50789506, COSV99175970; called by muse, mutect2, varscan2
- SLC28A2 | c.363G>A p.S121= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs771965795, COSV61665129; called by muse, mutect2, varscan2
- SMAD9 | c.33C>T p.F11= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100614469; called by muse, mutect2, varscan2
- STRIP2 | c.249C>T p.C83= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99973509; called by muse, mutect2, varscan2
- THBD | c.843C>T p.T281= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1432196644, COSV101001849; called by muse, mutect2
- TTN | c.102999G>A p.G34333= (on ENST00000591111; = p.G26909= on NM_003319.4) | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100597265; called by muse, mutect2
- TXNDC11 | c.1743G>A p.E581= (on ENST00000356957 / NM_001303447.2; = p.E554= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as COSV51597058, COSV99297343; called by muse, mutect2, varscan2
- HTR3A | c.917-21C>T | Intron (SNP) | VAF 29/107 reads (27%) | catalogued as rs1011531793, COSV100248295; called by muse, mutect2, varscan2
- TSPAN14 | chr10:80520745 C>T | 3'Flank (SNP) | VAF 89/323 reads (28%) | catalogued as COSV99627775; called by muse, mutect2, varscan2
